Gene-level copy-number profile of tumor specimen TARGET-40-PATMXR-01A from TARGET case TARGET-40-PATMXR, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.9 years (7,631 days).
Specimen TARGET-40-PATMXR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.7ba998c4-2439-5424-8a04-606898af75a9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATMXR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate.
https://portal.gdc.cancer.gov/files/000df005-cf31-4271-bc98-f4700796c66e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 609; copy number 1: 906; copy number 2: 11,064; copy number 3: 22,208; copy number 4: 17,002; copy number 5: 4,661; copy number 6: 1,795; copy number 7: 851; copy number 8: 703; copy number 9: 328; copy number 10: 52; copy number 11: 38; copy number 13: 6.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:67,456,346–68,329,899, 12 genes: AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549.
- chr6:83,852,312–84,227,643, 7 genes (within-gene range 0–2): AL139232.1, RIPPLY2, CYB5R4, AL034347.1, LINC02857, MRAP2, CEP162.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr13:48,296,162–50,910,764, 61 genes (broad region; genes not listed).
- chr17:3,411,370–3,424,070, 1 gene: OR3A3.
- chr21:24,306,939–24,547,942, 1 gene (within-gene range 0–2): LINC01684.
- chr21:46,458,891–46,570,015, 1 gene (within-gene range 0–1): DIP2A.
- chr21:46,525,618–46,665,124, 4 genes: RNU6-396P, S100B, PRMT2, DSTNP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,977 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,811,602–88,685,204, 51 genes, copy number 7 (within-gene range 6–7): LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6, COL24A1, RNA5SP51, AC104455.1, LINC02795, ODF2L, MIR7856, AC119749.1, CLCA2, CLCA1, CLCA4, CDCA4P2, CLCA4-AS1, CLCA3P, CLCA4-AS1, SH3GLB1, AL049597.1, AL355981.1, SELENOF, HS2ST1, AL121989.1, AC093155.3, AC093155.2, AC093155.1, LINC01140, LINC02801, LMO4, LINC01364, RNA5SP52, PKN2-AS1, AL445437.1, AL049861.1.
- chr1:94,529,173–94,895,246, 6 genes, copy number 7 (within-gene range 6–7): F3, AC093117.1, SLC44A3-AS1, KATNBL1P2, MIR378G, SLC44A3.
- chr1:97,077,743–97,995,000, 1 gene, copy number 7 (within-gene range 6–7): DPYD.
- chr1:97,394,154–98,272,658, 13 genes, copy number 7: DPYD-IT1, SEC63P1, RPL26P9, AC114878.1, DPYD-AS2, AC114878.2, MIR137HG, BX005019.1, MIR2682, MIR137, AC104453.1, NFU1P2, LINC01776.
- chr7:130,380,339–130,388,114, 1 gene, copy number 7: CPA1.
- chr8:2,493,876–10,428,891, 195 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:12,945,642–21,298,168, 117 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:95,947,781–108,787,594, 231 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr8:109,777,912–110,632,394, 9 genes, copy number 11 (within-gene range 4–11): AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1.
- chr8:114,791,653–116,325,062, 5 genes, copy number 7 (within-gene range 6–7): CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276.
- chr8:132,866,958–133,571,940, 13 genes, copy number 8 (within-gene range 6–8): TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr8:140,094,894–145,066,685, 203 genes, copy number 7–8 (broad region; genes not listed).
- chr9:1,980,290–12,058,227, 127 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr9:12,287,320–17,503,923, 65 genes, copy number 7–8 (broad region; genes not listed).
- chr13:77,919,689–78,617,328, 1 gene, copy number 7 (within-gene range 6–7): OBI1-AS1.
- chr13:78,275,720–78,910,542, 12 genes, copy number 7: AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2.
- chr13:92,239,835–96,053,482, 45 genes, copy number 7: AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24.
- chr13:96,169,545–96,169,847, 1 gene, copy number 7: RN7SL164P.
- chr13:101,710,804–102,402,457, 1 gene, copy number 7 (within-gene range 5–7): FGF14.
- chr13:101,967,642–104,815,069, 30 genes, copy number 7: MIR2681, LIPT1P1, RNY1P2, MIR4705, RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2, AL162717.1, LINC01309, ATP6V1G1P7, AL136524.1, RPL7P45.
- chr13:106,773,623–114,337,626, 140 genes, copy number 7–10 (broad region; genes not listed).
- chr14:22,630,929–22,644,352, 1 gene, copy number 8 (within-gene range 4–8): OR6J1.
- chr16:34,139,189–35,912,516, 91 genes, copy number 8 (broad region; genes not listed).
- chr17:69,961,568–78,425,114, 264 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr21:29,536,933–30,643,136, 41 genes, copy number 7 (within-gene range 4–7): GRIK1, AP000238.1, GRIK1-AS1, AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1, KRTAP19-1, KRTAP19-2, KRTAP19-3, KRTAP19-4, KRTAP19-5, KRTAP19-9P, KRTAP19-10P, AP000567.1, KRTAP19-11P, KRTAP19-6, KRTAP19-7, KRTAP22-2, KRTAP6-3, KRTAP6-2, KRTAP22-1, KRTAP6-1, KRTAP20-1, KRTAP20-4, KRTAP20-2, KRTAP20-3.
- chr21:34,787,801–36,004,667, 1 gene, copy number 8 (within-gene range 4–8): RUNX1.
- chr21:35,136,638–46,097,530, 312 genes, copy number 7–9 (within-gene range 1–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 906. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
